Gene-level copy-number profile of tumor specimen MP2PRT-PATYWT-TMP1-A from MP2PRT case MP2PRT-PATYWT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,827 days).
Specimen MP2PRT-PATYWT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 79d6e589-f13e-460d-9098-0e8f66f80b09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATYWT-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/9d1b703a-a63c-49d6-b148-fdeb4fe04bde

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 98; copy number 2: 58,268.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,170,775–89,275,787, 14 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–2): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 98. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
